Somatic mutation profile of tumor specimen TCGA-CG-5721-01A (aliquot TCGA-CG-5721-01A-11D-1600-08) from TCGA case TCGA-CG-5721, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.2 years (21,244 days).
Specimen TCGA-CG-5721-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82f4aeed-07f7-4bfc-bf9a-9137cb109bf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5721-11A (Solid Tissue Normal), aliquot TCGA-CG-5721-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/018c456e-b983-4fac-8859-4e9519ddbde9

The open-access MAF lists 4,865 somatic variants for this specimen: 3,651 protein-altering or splice-affecting, 1,117 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,832, Silent 1,117, Frame Shift Del 534, Splice Site 85, Frame Shift Ins 76, Nonsense Mutation 73, Intron 50, Splice Region 35, RNA 18, In Frame Del 12, 3'UTR 12, 5'Flank 10.

Variants (750 of 4,865; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs267607165, CM100196, COSV100206073; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGL | c.3911del p.N1304Ifs*10 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- AHI1 | c.909_910dup p.T304Kfs*24 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.9022C>T p.R3008C | Missense Mutation (SNP) | VAF 25/150 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782292, CM000656, COSV53730980, COSV53739432; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRIP1 | c.1510del p.I504Sfs*22 | Frame Shift Del (DEL) | VAF 72/363 reads (20%) | catalogued as rs775735278, CD1512644, COSV52002650; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CHD7 | c.8961_8962dup p.D2988Gfs*4 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs771806027, CI084262; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel
- CTNNB1 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 51/257 reads (20%) | catalogued as rs775104326, CM150339, COSV62693690, COSV62728824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHX30 | c.2344C>T p.R782W (on ENST00000445061 / NM_138615.3; = p.R743W on NM_014966.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753242774, COSV53136286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 42/209 reads (20%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- HGD | c.1111dup p.H371Pfs*4 | Frame Shift Ins (INS) | VAF 22/155 reads (14%) | catalogued as rs397515516; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KIF5A | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387907288, CM090639, CM090640, COSV54052576; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 56/95 reads (59%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PAX2 | c.76dup p.V26Gfs*28 | Frame Shift Ins (INS) | VAF 10/58 reads (17%) | catalogued as rs75462234; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 28/159 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PROK2 | c.297del p.F99Lfs*28 (on ENST00000295619 / NM_001126128.2; = p.F78Lfs*28 on NM_021935.4) | Frame Shift Del (DEL) | VAF 19/124 reads (15%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RIN2 | c.1878del p.I627Sfs*4 (on ENST00000255006 / NM_001242581.1; = p.I578Sfs*4 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs397515538; ClinVar: pathogenic; called by pindel, varscan2
- RYR1 | c.11320del p.A3774Rfs*8 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs768698639, CM073325, COSV100614110; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- SCN5A | c.3908G>A p.R1303Q (on ENST00000333535 / NM_198056.3; = p.R1302Q on NM_000335.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs977717858, COSV61119181; ClinVar: likely pathogenic; called by muse, mutect2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC4A1 | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs28931584, CM971385, COSV52258208; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TCF20 | c.364dup p.Q122Pfs*12 | Frame Shift Ins (INS) | VAF 38/218 reads (17%) | catalogued as rs777979354; ClinVar: pathogenic; called by mutect2, varscan2
- TGM1 | c.566dup p.S190Qfs*49 | Frame Shift Ins (INS) | VAF 14/113 reads (12%) | catalogued as rs1211601030; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, varscan2
- A1BG | c.791T>C p.F264S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54050261; called by muse, mutect2, varscan2
- AADACL2 | c.1054A>G p.T352A | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV62929829; called by muse, mutect2, varscan2
- AADAT | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs139598358; called by muse, mutect2, varscan2
- ABCA1 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs562901144, COSV66064583; called by muse, mutect2, varscan2
- ABCA10 | c.3900G>T p.E1300D | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV52219617, COSV52229509; called by muse, mutect2, varscan2
- ABCA10 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52219627; called by muse, mutect2
- ABCA12 | c.6960C>T p.T2320= (on ENST00000272895 / NM_173076.3; = p.T2002= on NM_015657.3) | Splice Region (SNP) | VAF 28/184 reads (15%) | catalogued as rs1021345094, COSV55952672; called by muse, mutect2, varscan2
- ABCA2 | c.2270T>C p.I757T (on ENST00000614293; = p.I727T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55799055; called by muse, mutect2
- ABCA3 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV57051010; called by muse, varscan2
- ABCA4 | c.1118T>C p.L373S | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV64671934; called by muse, mutect2, varscan2
- ABCB6 | c.1969-1G>T p.X657_splice | Splice Site (SNP) | VAF 20/95 reads (21%) | catalogued as COSV54694006; called by muse, mutect2, varscan2
- ABCC12 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60912531; called by muse, mutect2, varscan2
- ABCC2 | c.1634T>C p.V545A | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV64985081; called by muse, mutect2
- ABCC2 | c.3119T>C p.I1040T | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as rs754501570, COSV64985085; called by muse, mutect2, varscan2
- ABCC3 | c.1886T>C p.I629T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1221068133, COSV53318750; called by muse, mutect2, varscan2
- ABCC3 | c.4441G>A p.A1481T | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs539211035, COSV53318763; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC9 | c.3859A>G p.T1287A | Missense Mutation (SNP) | VAF 65/373 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53965406; called by muse, mutect2, varscan2
- ABCC9 | c.1411T>C p.Y471H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53965419; called by muse, mutect2, varscan2
- ABCD2 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as COSV100429792; called by muse, mutect2, varscan2
- ABCD3 | c.1897C>T p.H633Y | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64642564; called by muse, mutect2, varscan2
- ABCD4 | c.1507T>C p.S503P | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV53991372; called by muse, mutect2
- ABCD4 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53991386; called by muse, mutect2, varscan2
- ABCF3 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs556532781, COSV53047409; called by muse, mutect2, varscan2
- ABHD1 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV53205197; called by muse, mutect2, varscan2
- ABHD12 | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59284516; called by muse, mutect2, varscan2
- ABHD3 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56675951; called by muse, mutect2, varscan2
- ABHD4 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as rs148116289, COSV99360453; called by muse, mutect2, varscan2
- ABHD6 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as rs373121590; called by muse, varscan2
- ABLIM3 | c.1027A>G p.R343G | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV58640475; called by muse, mutect2, varscan2
- ABR | c.580G>A p.A194T (on ENST00000302538 / NM_021962.5; = p.A157T on NM_001092.5) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99348564; called by muse, mutect2
- AC005833.1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs373711782, COSV52895583; called by muse, mutect2, varscan2
- AC011455.2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs1290909544, COSV55498816; called by muse, mutect2, varscan2
- AC090517.4 | c.1936T>C p.Y646H | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50996053; called by muse, mutect2, varscan2
- AC098582.1 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52018480; called by muse, mutect2, varscan2
- AC107871.1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | PolyPhen possibly damaging (0.81); catalogued as rs372793839; called by muse, mutect2, varscan2
- ACACA | c.4187G>A p.R1396Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1484000480; called by muse, varscan2
- ACACB | c.5584C>A p.L1862M | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58130525; called by muse, varscan2
- ACAD10 | c.2998G>A p.A1000T | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as rs757552774, COSV58155028; called by muse, varscan2
- ACAD9 | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1330163471, COSV58306827; called by muse, mutect2, varscan2
- ACAT1 | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.732); catalogued as COSV56186972; called by muse, mutect2, varscan2
- ACAT2 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV58457840; called by muse, mutect2, varscan2
- ACCSL | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs199703277, COSV66580585; called by muse, mutect2, varscan2
- ACD | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.014); catalogued as COSV54666483; called by muse, mutect2, varscan2
- ACE | c.3503+1G>A p.X1168_splice | Splice Site (SNP) | VAF 25/130 reads (19%) | catalogued as rs779188587, CS120968, COSV52004663; called by muse, mutect2, varscan2
- ACER3 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV53597813; called by muse, mutect2, varscan2
- ACIN1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs776587268, COSV52974414; called by muse, mutect2, varscan2
- ACLY | c.845del p.G282Vfs*14 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | catalogued as COSV100709609; called by mutect2, varscan2
- ACOT11 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59346815; called by muse, mutect2, varscan2
- ACOT11 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as COSV59346828; called by muse, varscan2
- ACOT7 | c.448+2T>C p.X150_splice (on ENST00000377855 / NM_181864.3; = p.X140_splice on NM_007274.4) | Splice Site (SNP) | VAF 18/101 reads (18%) | catalogued as COSV64112461; called by muse, mutect2, varscan2
- ACP6 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs1553209922, COSV65076428; called by muse, mutect2, varscan2
- ACR | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576896841, COSV53360582; called by muse, mutect2
- ACSS1 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60218585; called by muse, mutect2, varscan2
- ACTL6B | c.695del p.P232Qfs*24 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | catalogued as rs779550102; called by mutect2, pindel, varscan2
- ACTL7A | c.598T>C p.Y200H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.972); catalogued as COSV61776376; called by muse, mutect2, varscan2
- ACTL7A | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758729154, COSV61776227; called by muse, mutect2
- ACTN2 | c.1768A>G p.N590D | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV63973267; called by muse, mutect2, varscan2
- ACTR1B | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567001834, COSV56703468; called by muse, mutect2, varscan2
- ACTR2 | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.671); catalogued as COSV53199960; called by muse, mutect2, varscan2
- ACVR1C | c.305-2A>G p.X102_splice | Splice Site (SNP) | VAF 31/127 reads (24%) | catalogued as COSV54644635; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 85/196 reads (43%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACY3 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54828314; called by muse, mutect2, varscan2
- ADA2 | c.904G>A p.A302T (on ENST00000262607; = p.A61T on NM_177405.3) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1333898789, COSV52830715; called by muse, mutect2, varscan2
- ADAD1 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV56642281; called by muse, mutect2, varscan2
- ADAM17 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.255); catalogued as COSV60398020; called by muse, mutect2, varscan2
- ADAM18 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs568269707, COSV55845206; called by muse, mutect2, varscan2
- ADAM23 | c.1255T>C p.Y419H | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52210461; called by muse, mutect2, varscan2
- ADAM29 | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63661725; called by muse, mutect2, varscan2
- ADAMDEC1 | c.147del p.K49Nfs*32 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | catalogued as rs879360738; called by mutect2, pindel, varscan2
- ADAMTS13 | c.1774T>C p.F592L | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63020495; called by muse, mutect2, varscan2
- ADAMTS16 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550837516, COSV56982433; called by muse, mutect2, varscan2
- ADAMTS17 | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs772506694, COSV51475476, COSV99170361; called by muse, mutect2, varscan2
- ADAMTS19 | c.2595T>G p.H865Q | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV50736049; called by muse, mutect2, varscan2
- ADAMTS5 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV53177047; called by muse, mutect2, varscan2
- ADAMTS9 | c.4643A>G p.D1548G | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV55777177; called by muse, mutect2, varscan2
- ADAMTS9 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55777206; called by muse, mutect2, varscan2
- ADAR | c.2119T>A p.S707T | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.952); catalogued as COSV52713275; called by muse, mutect2, varscan2
- ADCY1 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336408449, COSV52031872; called by muse, mutect2, varscan2
- ADCY3 | c.1268del p.G423Afs*19 | Frame Shift Del (DEL) | VAF 28/145 reads (19%) | catalogued as rs754914420; ClinVar: risk factor; called by mutect2, pindel, varscan2
- ADCY5 | c.2630A>G p.N877S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1039981411, COSV59195654; called by muse, mutect2, varscan2
- ADCY7 | c.2779G>A p.V927M | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1327486454, COSV54265098; called by muse, mutect2, varscan2
- ADD2 | c.930G>T p.Q310H | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.246); catalogued as COSV52456812; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 45/122 reads (37%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs867338030, COSV74142565; called by muse, mutect2, varscan2
- ADGRA2 | c.3161A>G p.Y1054C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55103043; called by muse, mutect2
- ADGRA3 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51561075; called by muse, varscan2
- ADGRD1 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.012); catalogued as COSV55441027; called by muse, mutect2, varscan2
- ADGRG2 | c.2230+2T>C p.X744_splice (on ENST00000379869 / NM_001079858.3; = p.X741_splice on NM_005756.4) | Splice Site (SNP) | VAF 29/139 reads (21%) | catalogued as COSV61338084; called by muse, mutect2, varscan2
- ADGRG2 | c.919T>C p.S307P (on ENST00000379869 / NM_001079858.3; = p.S304P on NM_005756.4) | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.741); catalogued as COSV61338090; called by muse, mutect2, varscan2
- ADGRG2 | c.532A>G p.T178A (on ENST00000379869 / NM_001079858.3; = p.T175A on NM_005756.4) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV61338095; called by muse, mutect2, varscan2
- ADGRL2 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365207880, COSV54658009, COSV54680988; called by muse, mutect2, varscan2
- ADGRL3 | c.1609A>G p.T537A (on ENST00000506720 / NM_001322402.2; = p.T469A on NM_015236.6) | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV72229979; called by muse, mutect2, varscan2
- ADH6 | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV52955443; called by muse, mutect2
- ADHFE1 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV52553973; called by muse, mutect2, varscan2
- ADIPOR2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 98/442 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs1407413750, COSV63945704; called by muse, mutect2, varscan2
- ADIRF | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV64394066; called by mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 40/224 reads (18%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP | c.1452A>G p.I484M | Missense Mutation (SNP) | VAF 125/600 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.694); catalogued as COSV62424791; called by muse, mutect2, varscan2
- ADORA2B | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58481599; called by muse, mutect2
- ADPRHL1 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62909989; called by muse, mutect2, varscan2
- ADPRS | c.395G>A p.C132Y | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV52880517; called by muse, mutect2
- ADSL | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53407055; called by muse, mutect2, varscan2
- AFAP1 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61794209; called by muse, mutect2, varscan2
- AFF3 | c.3194A>G p.Y1065C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57845571; called by muse, mutect2, varscan2
- AFF4 | c.3143G>T p.S1048I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54792795; called by muse, mutect2, varscan2
- AFTPH | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs1193217895, COSV53216623; called by muse, mutect2, varscan2
- AGAP2 | c.2251G>A p.A751T (on ENST00000547588 / NM_001122772.2; = p.A415T on NM_014770.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.171); catalogued as COSV57727280; called by muse, mutect2, varscan2
- AGAP6 | c.1322C>T p.A441V (on ENST00000374056 / NM_001365867.1; = p.A464V on NM_001077665.2) | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100929155; called by muse, mutect2, varscan2
- AGK | c.248del p.N83Mfs*13 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as COSV62595111; called by mutect2, pindel, varscan2
- AGO1 | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64594819; called by muse, mutect2, varscan2
- AGO1 | c.1395C>T p.L465= | Splice Region (SNP) | VAF 16/66 reads (24%) | catalogued as rs1023867293, COSV64594821; called by muse, mutect2, varscan2
- AGO2 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV55045987; called by muse, varscan2
- AGPAT4 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as rs1288833485, COSV57243953; called by muse, mutect2, varscan2
- AGPS | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs764836897, COSV51561213; called by muse, mutect2, varscan2
- AGTPBP1 | c.2080T>C p.Y694H (on ENST00000357081 / NM_001330701.2; = p.Y654H on NM_015239.2) | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61269729; called by muse, mutect2, varscan2
- AHCTF1 | c.2404G>A p.V802I (on ENST00000366508; = p.V776I on NM_015446.5) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1160209890, COSV58247401; called by muse, mutect2, varscan2
- AHDC1 | c.3421G>A p.V1141M | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55937434; called by muse, mutect2, varscan2
- AHNAK | c.4613A>G p.D1538G | Missense Mutation (SNP) | VAF 92/424 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57207345; called by muse, mutect2, varscan2
- AHNAK | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV57207362; called by muse, mutect2, varscan2
- AHNAK2 | c.13337A>T p.E4446V | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1303723141, COSV60910680; called by muse, mutect2, varscan2
- AHNAK2 | c.8310del p.D2771Mfs*2 | Frame Shift Del (DEL) | VAF 60/321 reads (19%) | catalogued as rs765035661; called by mutect2, pindel, varscan2
- AHNAK2 | c.7975A>G p.R2659G | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372141829; called by muse, varscan2
- AHNAK2 | c.7753del p.Q2585Sfs*2 | Frame Shift Del (DEL) | VAF 29/219 reads (13%) | catalogued as COSV100319127; called by pindel, varscan2
- AK9 | c.889A>G p.K297E | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV53420403; called by muse, mutect2, varscan2
- AKAP12 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs753094802, COSV53571409; called by muse, mutect2, varscan2
- AKAP12 | c.2844dup p.T949Hfs*4 | Frame Shift Ins (INS) | VAF 21/124 reads (17%) | catalogued as rs767490652; called by mutect2, pindel, varscan2
- AKAP12 | c.4685T>C p.V1562A | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53571418; called by muse, mutect2, varscan2
- AKAP13 | c.7613T>C p.V2538A (on ENST00000394518 / NM_007200.5; = p.V2542A on NM_006738.6) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs777033018, COSV63451641; called by mutect2, varscan2
- AKAP3 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV57415063; called by muse, mutect2, varscan2
- AKAP4 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV62073972; called by muse, mutect2
- AKAP6 | c.568A>G p.T190A | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV55208042, COSV99804246; called by muse, mutect2, varscan2
- AKAP6 | c.1244T>C p.V415A | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55208054; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8 | c.2041A>G p.T681A | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV54101628; called by muse, mutect2, varscan2
- AKAP8 | c.1145A>G p.D382G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV54101636; called by muse, mutect2
- AKAP9 | c.7976del p.N2659Mfs*3 (on ENST00000359028; = p.N2635Mfs*3 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | catalogued as rs1250599910; called by mutect2, pindel, varscan2
- AKNA | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99801026; called by muse, mutect2, varscan2
- ALCAM | c.1567A>G p.N523D | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV60246366; called by muse, mutect2, varscan2
- ALDH1A1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV52789792; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALDH4A1 | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51890926; called by muse, mutect2
- ALDH9A1 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758256843, COSV61339393; called by muse, mutect2, varscan2
- ALDOC | c.801A>G p.G267= | Splice Region (SNP) | VAF 35/201 reads (17%) | catalogued as COSV52023950; called by muse, mutect2, varscan2
- ALK | c.1919G>A p.G640E | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs868425819, COSV101202595, COSV66561543; called by muse, mutect2, varscan2
- ALKBH8 | c.49_51del p.K17del | In Frame Del (DEL) | VAF 10/98 reads (10%) | catalogued as rs766827587; called by pindel, varscan2
- ALMS1 | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV52505318; called by muse, mutect2, varscan2
- ALS2CL | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs374258849; called by muse, mutect2, varscan2
- ALX1 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100374578; called by muse, mutect2, varscan2
- AMBRA1 | c.1238G>T p.G413V (on ENST00000458649 / NM_001367468.1; = p.G323V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV54050684; called by muse, mutect2, varscan2
- AMER1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs767567473, COSV57656123; called by muse, mutect2, varscan2
- AMER3 | c.1210A>G p.S404G | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV58465688; called by muse, mutect2, varscan2
- AMER3 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs762583873, COSV58465694; called by muse, mutect2, varscan2
- AMPH | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV57736738; called by muse, mutect2, varscan2
- AMY2A | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 63/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214287, COSV70214761; called by muse, mutect2, varscan2
- ANAPC11 | c.142T>C p.W48R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV58710918; called by mutect2, varscan2
- ANGPT2 | c.1348T>C p.C450R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57335452; called by muse, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 40/222 reads (18%) | catalogued as rs34047276; called by mutect2, varscan2
- ANK3 | c.8030T>C p.V2677A | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55049137; called by muse, mutect2, varscan2
- ANKAR | c.3868C>T p.R1290C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs374926234; called by muse, mutect2, varscan2
- ANKFY1 | c.658T>C p.Y220H | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs977569894, COSV58915447; called by muse, varscan2
- ANKLE1 | c.827T>C p.V276A (on ENST00000394458; = p.V222A on NM_152363.6) | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV63920118; called by muse, mutect2, varscan2
- ANKMY1 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56031447; called by muse, mutect2, varscan2
- ANKRD11 | c.6445G>A p.A2149T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as rs1024078594, COSV56357358; called by muse, mutect2, varscan2
- ANKRD17 | c.4284+2T>C p.X1428_splice | Splice Site (SNP) | VAF 30/207 reads (14%) | catalogued as COSV58217431; called by muse, mutect2, varscan2
- ANKRD17 | c.2036T>C p.V679A | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58217440; called by muse, mutect2, varscan2
- ANKRD26 | c.4242G>C p.E1414D | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV65774578; called by muse, mutect2, varscan2
- ANKRD26 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs917180921, COSV65793405; called by muse, mutect2, varscan2
- ANKRD28 | c.2169A>G p.I723M | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV67517348; called by muse, mutect2, varscan2
- ANKRD34B | c.1434del p.V479Cfs*20 | Frame Shift Del (DEL) | VAF 58/301 reads (19%) | catalogued as rs1291304333; called by mutect2, pindel, varscan2
- ANKRD34B | c.1247del p.P416Qfs*4 | Frame Shift Del (DEL) | VAF 26/205 reads (13%) | catalogued as rs779065930, COSV100103683; called by mutect2, pindel, varscan2
- ANLN | c.2301T>C p.T767= | Splice Region (SNP) | VAF 22/116 reads (19%) | catalogued as COSV56074622; called by muse, mutect2, varscan2
- ANO4 | c.422A>G p.N141S (on ENST00000392977 / NM_001286615.2; = p.N106S on NM_178826.4) | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV54589335; called by muse, mutect2, varscan2
- ANO4 | c.618A>G p.I206M (on ENST00000392977 / NM_001286615.2; = p.I171M on NM_178826.4) | Missense Mutation (SNP) | VAF 123/595 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV54589348; called by muse, varscan2
- ANO6 | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57658343; called by muse, varscan2
- ANOS1 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV52917251; called by muse, mutect2, varscan2
- ANXA13 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV51621909; called by muse, varscan2
- ANXA6 | c.1817A>G p.D606G | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62905860; called by muse, mutect2, varscan2
- AOC2 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV53198524; called by muse, mutect2, varscan2
- AP1B1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1219112521, COSV58015477; called by muse, mutect2, varscan2
- AP3B2 | c.3034C>T p.R1012W (on ENST00000261722; = p.R1006W on NM_004644.5) | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs368331201; called by muse, mutect2, varscan2
- AP3D1 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV61425723; called by muse, mutect2, varscan2
- AP5Z1 | c.2182A>G p.T728A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV62240925; called by muse, mutect2
- APC | c.5337A>G p.I1779M | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748063409, COSV57332478; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- APEX1 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV51657264; called by muse, mutect2, varscan2
- APLNR | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746176980, COSV57241783; called by muse, mutect2, varscan2
- APOBEC1 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.916); catalogued as rs745537786, COSV57548468; called by muse, mutect2, varscan2
- APOL1 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV59868657; called by muse, mutect2, varscan2
- APPL2 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs143353224; called by muse, mutect2, varscan2
- APTX | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as COSV58927975; called by muse, mutect2, varscan2
- AQP7 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV53010193; called by muse, mutect2, varscan2
- AQR | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.392); catalogued as rs771045397, COSV50030594; called by muse, mutect2, varscan2
- AQR | c.1394A>G p.Y465C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50030608; called by muse, varscan2
- AR | c.2547T>G p.N849K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65954187; called by muse, mutect2, varscan2
- ARAF | c.1132T>C p.F378L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV51691820; called by muse, mutect2, varscan2
- ARAP1 | c.2768T>C p.L923P (on ENST00000393609 / NM_001040118.2; = p.L678P on NM_015242.4) | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV61990140; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 30/180 reads (17%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGAP3 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV54311023; called by muse, mutect2, varscan2
- ARFGEF1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369515490, COSV51604648; called by muse, mutect2, varscan2
- ARFRP1 | c.29_34del p.K10_Y11del | In Frame Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs755724981; called by mutect2, pindel
- ARHGAP28 | c.2074T>C p.Y692H (on ENST00000383472 / NM_001366230.1; = p.Y533H on NM_001010000.3) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV58646566; called by muse, mutect2, varscan2
- ARHGAP31 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV51790326, COSV99956677; called by muse, varscan2
- ARHGAP35 | c.2825T>C p.V942A | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV68329843; called by muse, mutect2, varscan2
- ARHGAP39 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs771248905, COSV52768180; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as COSV57429840; called by mutect2, pindel
- ARHGEF10 | c.3410C>T p.T1137M (on ENST00000398564; = p.T1112M on NM_014629.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs772205292, COSV50644032; called by muse, mutect2, varscan2
- ARHGEF11 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs775705969, COSV63810365, COSV63811010; called by muse, mutect2, varscan2
- ARHGEF15 | c.1936T>C p.C646R | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.497); catalogued as COSV62724647; called by muse, mutect2, varscan2
- ARHGEF37 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV61368241; called by muse, mutect2, varscan2
- ARHGEF5 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 31/320 reads (10%) | catalogued as rs1470999644, COSV99283188; called by muse, mutect2, varscan2
- ARID1A | c.1636del p.Q546Rfs*73 | Frame Shift Del (DEL) | VAF 40/229 reads (17%) | catalogued as COSV61383992, COSV61391080; called by mutect2, pindel, varscan2
- ARID1B | c.4423C>G p.P1475A | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV51653462; called by muse, mutect2, varscan2
- ARID3C | c.884A>G p.N295S | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52406772; called by muse, mutect2, varscan2
- ARID5A | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs375719718; called by muse, mutect2, varscan2
- ARID5B | c.2870T>C p.V957A | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1193575018, COSV54416560; called by muse, mutect2, varscan2
- ARL13B | c.458T>C p.V153A (on ENST00000394222 / NM_001174150.2; = p.V46A on NM_144996.4) | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV57396959; called by muse, varscan2
- ARMCX5 | c.523T>C p.W175R | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99863551; called by muse, mutect2
- ARPC4 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55028231; called by muse, mutect2, varscan2
- ARPP21 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV51794116; called by muse, mutect2, varscan2
- ARPP21 | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV51794130; called by muse, mutect2
- ARRDC1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs376105916; called by muse, mutect2, varscan2
- ARSB | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV53720233; called by muse, mutect2, varscan2
- ARSI | c.998T>C p.L333P | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60816917; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSK | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66169336; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 50/114 reads (44%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASB11 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 119/197 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV60354618; called by muse, mutect2, varscan2
- ASB15 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV51924601; called by muse, mutect2, varscan2
- ASCC3 | c.4831A>G p.T1611A | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as COSV64973184; called by muse, mutect2, varscan2
- ASF1B | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54615706; called by muse, mutect2, varscan2
- ASIC2 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56757843; called by muse, mutect2, varscan2
- ASPHD2 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV53218386; called by muse, mutect2, varscan2
- ASPM | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760611432, COSV54126697; called by muse, mutect2, varscan2
- ASPSCR1 | c.1190T>C p.F397S | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774213125, COSV60727753; called by muse, varscan2
- ASS1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs576636333, COSV100752602, COSV61688708; called by mutect2, varscan2
- ASTN2 | c.3520A>G p.T1174A (on ENST00000313400 / NM_001365069.1; = p.T1123A on NM_014010.5) | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV56001158; called by muse, mutect2, varscan2
- ASXL1 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1162384519, COSV60105030; called by muse, mutect2
- ASXL3 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.23); catalogued as rs1421447131, COSV52460885; called by muse, mutect2, varscan2
- ASXL3 | c.5109A>C p.Q1703H | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV52460893; called by muse, mutect2, varscan2
- ATAD1 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57756150; called by muse, mutect2, varscan2
- ATAD2 | c.825T>A p.D275E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs149531312; called by muse, varscan2
- ATF7IP | c.2675T>C p.V892A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV53767894; called by muse, mutect2, varscan2
- ATG2A | c.1970A>G p.D657G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV65966150; called by muse, mutect2, varscan2
- ATG2B | c.6031A>G p.I2011V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1384267282, COSV55889762; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 35/148 reads (24%) | catalogued as rs771531141; called by mutect2, varscan2
- ATG4A | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58964840; called by muse, mutect2
- ATL2 | c.1382A>G p.K461R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV60050837; called by muse, mutect2, varscan2
- ATM | c.4222C>T p.L1408F | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1565455224, COSV53727629, COSV53733404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.7700A>G p.N2567S | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV53733420; called by muse, mutect2, varscan2
- ATMIN | c.2253A>G p.I751M | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55145556; called by muse, mutect2, varscan2
- ATOH1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60037532; called by muse, mutect2, varscan2
- ATP10A | c.2785C>G p.Q929E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV63515033; called by muse, mutect2, varscan2
- ATP11A | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV52107989; called by muse, mutect2, varscan2
- ATP11B | c.1837dup p.T613Nfs*7 | Frame Shift Ins (INS) | VAF 7/52 reads (13%) | catalogued as rs1560101433; called by mutect2, pindel, varscan2
- ATP11C | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59560752; called by muse, mutect2, varscan2
- ATP12A | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs145531717, COSV54511986; called by muse, mutect2, varscan2
- ATP1A3 | c.2006A>G p.H669R (on ENST00000545399 / NM_001256214.2; = p.H656R on NM_152296.5) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV57486145; called by muse, mutect2, varscan2
- ATP23 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.886); catalogued as rs200432568; called by muse, mutect2, varscan2
- ATP2A3 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs373288442; called by muse, mutect2, varscan2
- ATP4A | c.1847A>G p.K616R | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52866659; called by muse, mutect2, varscan2
- ATP5MD | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58915401; called by muse, varscan2
- ATP6AP2 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65797382; called by muse, mutect2, varscan2
- ATP6AP2 | c.962T>C p.I321T (on ENST00000378438; = p.I322T on NM_005765.3) | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV65797393; called by muse, mutect2, varscan2
- ATP6V1B1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV52265368; called by muse, mutect2, varscan2
- ATP6V1B1 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52268582; called by muse, mutect2, varscan2
- ATP6V1F | c.163T>C p.F55L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV50799995; called by muse, mutect2, varscan2
- ATP7B | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs763787884, COSV54436437; called by muse, mutect2, varscan2
- ATP8B3 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV59541155; called by muse, mutect2, varscan2
- ATRAID | c.791C>A p.A264D (on ENST00000611786; = p.A151D on NM_016085.5) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53024747; called by muse, varscan2
- ATRNL1 | c.1222C>T p.Q408* | Nonsense Mutation (SNP) | VAF 57/325 reads (18%) | catalogued as rs782070859, COSV61799808; called by muse, mutect2, varscan2
- ATXN1 | c.1618A>G p.T540A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55211438; called by muse, varscan2
- ATXN1 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV55211446; called by muse, varscan2
- ATXN3 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs965403034, COSV61494222; called by muse, mutect2, varscan2
- ATXN7 | c.1561T>C p.F521L | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs753692014, COSV55748975; called by muse, mutect2, varscan2
- ATXN7L3 | c.984G>C p.K328N (on ENST00000389384 / NM_001382309.1; = p.K335N on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV100116331; called by muse, mutect2, varscan2
- AUNIP | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 69/370 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65352543; called by muse, mutect2, varscan2
- AUP1 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1197335429, COSV99239945; called by muse, varscan2
- AURKC | c.869A>T p.H290L (on ENST00000302804 / NM_001015878.2; = p.H256L on NM_003160.3) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57137352; called by muse, mutect2, varscan2
- AUTS2 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV61389283; called by muse, mutect2
- AUTS2 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61389289; called by muse, mutect2, varscan2
- AVPR1A | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV54545921; called by muse, mutect2, varscan2
- B2M | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62563405; called by muse, varscan2
- B3GALNT2 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs757654545, COSV58356028; called by muse, mutect2, varscan2
- B3GALT2 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as rs1205657252, COSV66463903; called by muse, mutect2, varscan2
- B3GAT1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56995030; called by muse, mutect2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs770737105, COSV57327371; called by mutect2, pindel, varscan2
- B4GALT5 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65493064; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | catalogued as COSV59620972; called by mutect2, varscan2
- BACE1 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV57284135; called by muse, mutect2, varscan2
- BACE1 | c.235A>G p.M79V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.714); catalogued as COSV57284146; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 25/157 reads (16%) | catalogued as rs748639705; called by mutect2, pindel, varscan2
- BACH2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV57587489; called by muse, mutect2, varscan2
- BAG3 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV64841781; called by muse, mutect2
- BAG6 | c.344dup p.G116Wfs*11 | Frame Shift Ins (INS) | VAF 26/160 reads (16%) | catalogued as rs761315497; called by mutect2, varscan2
- BAIAP3 | c.1877A>G p.D626G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV50103751; called by muse, mutect2, varscan2
- BAZ1B | c.1378A>G p.T460A | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59989607; called by muse, mutect2, varscan2
- BBS2 | c.1527G>A p.R509= | Splice Region (SNP) | VAF 48/241 reads (20%) | catalogued as COSV55325578; called by muse, mutect2, varscan2
- BCL3 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV51233941; called by muse, mutect2, varscan2
- BCL9L | c.4050del p.K1351Rfs*10 | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | catalogued as COSV52682244; called by mutect2, pindel, varscan2
- BCL9L | c.1478del p.P493Rfs*9 | Frame Shift Del (DEL) | VAF 29/172 reads (17%) | catalogued as COSV52683193; called by mutect2, pindel, varscan2
- BCOR | c.5161A>T p.K1721* (on ENST00000378444 / NM_001123385.2; = p.K1687* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 36/55 reads (65%) | catalogued as COSV60703023; called by muse, mutect2, varscan2
- BCR | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760590010, COSV59928493; called by muse, varscan2
- BCS1L | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs143968821; called by muse, mutect2, varscan2
- BDKRB2 | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV60014078; called by muse, mutect2
- BEND4 | c.1517A>G p.N506S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.041); catalogued as COSV72468990; called by muse, mutect2, varscan2
- BFSP2 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as rs901605072, COSV56587255; called by muse, mutect2, varscan2
- BHMT | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57153823; called by muse, mutect2, varscan2
- BICC1 | c.471del p.V158* | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | catalogued as rs1198651930, COSV65857425; called by mutect2, pindel, varscan2
- BIRC6 | c.3680T>C p.V1227A | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV70196983; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2404A>G p.M802V | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1230658675, COSV63244385; called by muse, mutect2, varscan2
- BLK | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52050229; called by muse, mutect2, varscan2
- BLK | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs577905338, COSV52050242; called by muse, mutect2, varscan2
- BMP2 | c.1075G>C p.A359P | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV66577217; called by muse, mutect2, varscan2
- BMP4 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55415423; called by muse, mutect2, varscan2
- BMP5 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63701784; called by muse, mutect2, varscan2
- BMP7 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs919226290, COSV67780010; called by muse, mutect2, varscan2
- BNIP1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375030484; called by muse, mutect2, varscan2
- BNIPL | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54846222; called by muse, mutect2, varscan2
- BOD1L1 | c.6629A>T p.K2210M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50008178; called by muse, mutect2, varscan2
- BPIFB4 | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs759194336, COSV64950877; called by muse, mutect2, varscan2
- BRAF | c.2254G>A p.A752T (on ENST00000288602 / NM_001374244.1; = p.A712T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1481562268, COSV56110431; called by muse, mutect2
- BRCA2 | c.5428G>A p.V1810I | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs80358766, COSV101204520, COSV66450502; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, varscan2
- BRCA2 | c.6065C>T p.S2022L | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as CM993642, COSV66450510; called by muse, mutect2, varscan2
- BRD1 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53455664; called by muse, mutect2, varscan2
- BRD2 | c.725A>G p.H242R | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as rs1443857585, COSV66372726; called by muse, mutect2, varscan2
- BRD3 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57702161; called by muse, mutect2, varscan2
- BRD4 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV54583675; called by muse, mutect2, varscan2
- BRICD5 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376368009, COSV57026215; called by muse, mutect2, varscan2
- BRINP2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1218128208, COSV64176360; called by muse, mutect2, varscan2
- BRINP2 | c.1460C>G p.A487G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV64176366; called by muse, mutect2, varscan2
- BRINP3 | c.1805A>G p.D602G | Missense Mutation (SNP) | VAF 83/440 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV66517044; called by muse, mutect2, varscan2
- BRPF1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as rs770024332, COSV57403840; called by muse, mutect2, varscan2
- BRWD1 | c.4246A>G p.K1416E | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV60893767; called by muse, mutect2, varscan2
- BSDC1 | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV61981559; called by muse, mutect2, varscan2
- BSN | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56514640; called by mutect2, varscan2
- BSN | c.8221A>G p.S2741G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV56514651; called by muse, mutect2, varscan2
- BSN | c.11044C>T p.H3682Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.878); catalogued as COSV56514663; called by muse, mutect2, varscan2
- BSN | c.11722G>T p.A3908S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV56514673; called by muse, mutect2, varscan2
- BSPRY | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs748271499, COSV65242392; called by muse, mutect2, varscan2
- BTAF1 | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56431162; called by muse, mutect2, varscan2
- BTN2A1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as rs375240672; called by muse, mutect2, varscan2
- BTNL9 | c.556T>C p.W186R | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59794558; called by muse, mutect2, varscan2
- C10orf71 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV60504395; called by muse, mutect2, varscan2
- C10orf90 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1386226244, COSV52951341; called by muse, mutect2, varscan2
- C11orf24 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs536792763, COSV58505178, COSV58506145; called by muse, mutect2, varscan2
- C11orf42 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.342); catalogued as rs778033100, COSV56410242; called by muse, mutect2
- C12orf29 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV63554540; called by muse, mutect2, varscan2
- C12orf57 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as rs782161931, COSV57546532; called by muse, mutect2, varscan2
- C12orf60 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1315109679, COSV57451351; called by muse, mutect2
- C14orf28 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV57333018; called by muse, mutect2, varscan2
- C16orf78 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV54555439; called by muse, mutect2, varscan2
- C19orf12 | c.187G>A p.A63T (on ENST00000392278 / NM_001031726.3; = p.A52T on NM_031448.6) | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs376103979, CM139948, COSV60364374; called by muse, mutect2, varscan2
- C19orf53 | c.49A>G p.K17E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV50003888; called by muse, mutect2, varscan2
- C1orf112 | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.406); catalogued as rs1328857757, COSV99610178; called by muse, mutect2, varscan2
- C1orf210 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs897432979, COSV70682464; called by muse, mutect2, varscan2
- C1orf43 | c.373C>T p.R125C (on ENST00000368521 / NM_001297718.2; = p.R91C on NM_015449.4) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs537167939, COSV62966002; called by muse, mutect2, varscan2
- C20orf194 | c.3512A>G p.D1171G | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1430567883, COSV52693105; called by muse, mutect2, varscan2
- C2CD3 | c.1842A>G p.G614= | Splice Region (SNP) | VAF 44/192 reads (23%) | catalogued as COSV58091176; called by muse, varscan2
- C3 | c.1604A>G p.Y535C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412617510, COSV55570466; called by muse, mutect2
- C3orf20 | c.1672T>C p.S558P | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53783420; called by muse, mutect2, varscan2
- C5 | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs141543606; called by muse, mutect2, varscan2
- C5orf22 | c.772del p.S258Qfs*31 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs751259551; called by mutect2, varscan2
- C7orf33 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs376766533; called by muse, mutect2, varscan2
- C8B | c.672A>C p.Q224H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.952); catalogued as COSV64776825; called by muse, mutect2
- C8B | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.045); catalogued as rs370368238; called by muse, mutect2, varscan2
- C9orf135 | c.458T>A p.L153* | Nonsense Mutation (SNP) | VAF 30/153 reads (20%) | catalogued as COSV65874825; called by muse, mutect2, varscan2
- CA14 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52528511; called by muse, mutect2, varscan2
- CA4 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56281151; called by muse, mutect2, varscan2
- CA6 | c.32T>C p.F11S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV66261720; called by muse, mutect2, varscan2
- CABCOCO1 | c.387dup p.T130Hfs*17 | Frame Shift Ins (INS) | VAF 20/143 reads (14%) | catalogued as rs1163725062; called by mutect2, pindel, varscan2
- CABP4 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56885370; called by muse, mutect2, varscan2
- CACHD1 | c.3547C>T p.R1183C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs756541202, COSV51550217; called by muse, mutect2, varscan2
- CACHD1 | c.3704del p.P1235Lfs*7 | Frame Shift Del (DEL) | VAF 34/177 reads (19%) | catalogued as rs764948820; called by mutect2, pindel, varscan2
- CACNA1A | c.6141G>T p.K2047N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV64192733; called by muse, mutect2
- CACNA1C | c.3286T>C p.F1096L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV59704487; called by muse, mutect2, varscan2
- CACNA1D | c.6103A>G p.T2035A (on ENST00000350061 / NM_001128840.3; = p.T2055A on NM_000720.4) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV55441132; called by muse, mutect2, varscan2
- CACNA1E | c.4586T>C p.V1529A | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV62385786; called by muse, mutect2, varscan2
- CACNA1H | c.4738C>T p.R1580C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs777159526, COSV61986127; called by muse, mutect2, varscan2
- CACNA1I | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs376563942; called by muse, mutect2, varscan2
- CACNA1S | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV62937638; called by muse, varscan2
- CACNA1S | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs779799849, COSV100755369; called by mutect2, varscan2
- CACNA2D1 | c.1975A>G p.T659A (on ENST00000356253 / NM_001366867.1; = p.T647A on NM_000722.4) | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as COSV62375295; called by muse, mutect2, varscan2
- CACNA2D2 | c.1214A>G p.D405G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56561689; called by muse, mutect2, varscan2
- CACNA2D3 | c.1963T>C p.Y655H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55523449; called by muse, mutect2, varscan2
- CACNB2 | c.1181T>C p.V394A (on ENST00000324631 / NM_201596.3; = p.V339A on NM_000724.4) | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV56615976; called by muse, mutect2, varscan2
- CACNG2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55633350; called by muse, mutect2, varscan2
- CACTIN | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.028); catalogued as rs748592436, COSV50267155; called by muse, mutect2
- CACYBP | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV62881100; called by muse, mutect2, varscan2
- CADM3 | c.568G>A p.V190I (on ENST00000368125 / NM_001127173.3; = p.V224I on NM_021189.5) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63684501; called by muse, mutect2, varscan2
- CALHM1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs374297864; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 40/184 reads (22%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs754747174; called by pindel, varscan2
- CAND1 | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.706); catalogued as COSV73338564; called by muse, mutect2, varscan2
- CAND1 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.423); catalogued as COSV73338565; called by muse, mutect2, varscan2
- CAPN3 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs373919252, COSV58820318; called by muse, mutect2, varscan2
- CAPN3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs767398783, COSV58820330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPRIN2 | c.2128A>T p.M710L | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51831439; called by muse, mutect2, varscan2
- CAPS2 | c.1280T>C p.V427A | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.304); catalogued as COSV60824472; called by muse, mutect2, varscan2
- CARD11 | c.2909A>G p.Y970C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.198); catalogued as rs1225312452, COSV67797804; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD11 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV67797806; called by muse, mutect2, varscan2
- CARD11 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as rs1192456063, COSV62716874; called by muse, varscan2
- CARMIL2 | c.1976A>T p.Q659L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV58024318; called by muse, mutect2, varscan2
- CARMIL2 | c.2082G>A p.Q694= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58024339; called by muse, mutect2, varscan2
- CARNS1 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs956028667, COSV57048356; called by muse, mutect2
- CASKIN1 | c.875A>T p.Y292F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.627); catalogued as COSV58870893; called by muse, mutect2, varscan2
- CASP2 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.095); catalogued as COSV60081653; called by muse, mutect2
- CASR | c.2680G>A p.G894S (on ENST00000490131; = p.G971S on NM_000388.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56135532; called by muse, mutect2, varscan2
- CATSPER2 | c.1008A>G p.I336M | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV100390983; called by muse, mutect2, varscan2
- CATSPER4 | c.213G>A p.A71= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as rs758705723, COSV58792588; called by muse, mutect2
- CAVIN2 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV58423572; called by muse, mutect2, varscan2
- CBFA2T3 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV51924609, COSV99046941; called by muse, mutect2, varscan2
- CBLB | c.2236A>G p.T746A | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51423281; called by muse, mutect2
- CBLN1 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54653556; called by muse, mutect2, varscan2
- CC2D2A | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV67502683; called by muse, mutect2, varscan2
- CCDC138 | c.1805T>C p.I602T | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV99719528; called by muse, mutect2, varscan2
- CCDC146 | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.332); catalogued as COSV53545413; called by muse, mutect2, varscan2
- CCDC149 | c.264+1G>A p.X88_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | catalogued as rs777580063, COSV60877689; called by muse, mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 23/136 reads (17%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC160 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66251407; called by muse, mutect2, varscan2
- CCDC170 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53338085; called by muse, mutect2, varscan2
- CCDC171 | c.2764T>C p.C922R | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV52635967; called by muse, mutect2, varscan2
- CCDC178 | c.1377T>A p.D459E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.075); catalogued as COSV55765041; called by muse, mutect2, varscan2
- CCDC178 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55765057; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC183 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.229); catalogued as rs890269507; called by muse, mutect2
- CCDC185 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1457720901, COSV64820483, COSV64821540; called by muse, mutect2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | catalogued as rs751021664; called by mutect2, pindel, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 22/141 reads (16%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC28B | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1382933584, COSV52207984; called by muse, mutect2, varscan2
- CCDC33 | c.185+1G>T p.X62_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | catalogued as COSV58349370; called by muse, mutect2, varscan2
- CCDC40 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1052358414, COSV66473301; called by muse, mutect2, varscan2
- CCDC57 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.169); catalogued as COSV66433231; called by muse, mutect2, varscan2
- CCDC63 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV57527603; called by muse, mutect2, varscan2
- CCDC68 | c.386A>G p.N129S | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV61603261; called by muse, mutect2
- CCDC8 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.232); catalogued as rs1226516327, COSV56772648; called by muse, mutect2, varscan2
- CCDC80 | c.2638C>A p.P880T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV52815617; called by muse, mutect2, varscan2
- CCDC87 | c.1517A>G p.H506R | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV59578612; called by muse, mutect2
- CCDC88A | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55058451; called by muse, mutect2, varscan2
- CCDC93 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs142085524, COSV60120154; called by muse, mutect2, varscan2
- CCKBR | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV58099607; called by muse, mutect2
- CCNA1 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV55220489; called by muse, mutect2, varscan2
- CCNB1IP1 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.864); catalogued as rs781347633, COSV62302547; called by muse, mutect2, varscan2
- CCNYL1 | c.584T>C p.V195A (on ENST00000295414 / NM_001330218.2; = p.V125A on NM_152523.2) | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54939406; called by muse, varscan2
- CCR1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199998480, COSV56121818; called by muse, mutect2, varscan2
- CCSER1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs200732825; called by muse, mutect2, varscan2
- CCT7 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.885); catalogued as rs769701233, COSV54582798; called by muse, mutect2, varscan2
- CD101 | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as rs377145245; called by muse, mutect2, varscan2
- CD109 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV54644961; called by muse, mutect2, varscan2
- CD109 | c.3189+2T>C p.X1063_splice | Splice Site (SNP) | VAF 7/87 reads (8%) | catalogued as COSV54646940; called by muse, mutect2
- CD151 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58989460; called by muse, mutect2, varscan2
- CD180 | c.1853T>C p.L618P | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56517263; called by muse, mutect2, varscan2
- CD180 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs140099362; called by muse, mutect2, varscan2
- CD1C | c.891A>G p.G297= | Splice Region (SNP) | VAF 68/398 reads (17%) | catalogued as rs114722992, COSV63805962; called by muse, mutect2, varscan2
- CD2 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358000886, COSV65643398; called by muse, mutect2, varscan2
- CD22 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as COSV50050397; called by muse, mutect2, varscan2
- CD248 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.919); catalogued as rs539641105, COSV60935987; called by muse, mutect2, varscan2
- CD27 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs376790183, COSV56946208; called by muse, mutect2, varscan2
- CD27 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs760754193, COSV56946212; called by muse, mutect2, varscan2
- CD276 | c.596A>G p.Q199R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV59203002; called by muse, mutect2, varscan2
- CD300LF | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV56896272; called by muse, mutect2, varscan2
- CD46 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59731945; called by muse, mutect2, varscan2
- CD5L | c.329_331del p.E110del | In Frame Del (DEL) | VAF 56/314 reads (18%) | catalogued as rs780316594; called by pindel, varscan2
- CD7 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs781565740, COSV53938342; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 27/186 reads (15%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC14A | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs148639495; called by muse, varscan2
- CDC23 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758507688, COSV67509306; called by muse, mutect2, varscan2
- CDC27 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50369076; called by muse, mutect2, varscan2
- CDC42BPA | c.3863G>A p.R1288H (on ENST00000334218 / NM_001366019.2; = p.R1275H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.177); catalogued as rs752231516, COSV62005573; called by muse, mutect2, varscan2
- CDC42BPA | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62005593; called by muse, mutect2, varscan2
- CDC42BPB | c.4858C>T p.P1620S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63474258; called by muse, mutect2, varscan2
- CDC45 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54244184; called by muse, varscan2
- CDCA2 | c.2303A>G p.D768G | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs777214699, COSV57944944; called by muse, mutect2, varscan2
- CDH18 | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56909298; called by muse, mutect2, varscan2
- CDH23 | c.4220C>T p.T1407I | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56453393; called by muse, mutect2, varscan2
- CDH23 | c.6385A>T p.N2129Y | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV56453402; called by muse, mutect2, varscan2
- CDH3 | c.1505A>G p.D502G | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50555634; called by muse, mutect2
- CDH4 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759379228, COSV64645806; called by muse, mutect2, varscan2
- CDH6 | c.1028A>T p.Y343F | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV54066412; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDHR2 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs115283964, COSV56136028; called by muse, mutect2, varscan2
- CDHR2 | c.1625A>G p.N542S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV56136041; called by mutect2, varscan2
- CDHR2 | c.2161G>A p.A721T | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs116786975, COSV56136051; called by muse, mutect2, varscan2
- CDHR2 | c.2887G>A p.V963I | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756472116, COSV56136062; called by muse, mutect2, varscan2
- CDHR2 | c.3239A>G p.Y1080C | Missense Mutation (SNP) | VAF 103/512 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56136069; called by muse, mutect2, varscan2
- CDK12 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs370304179; called by muse, mutect2, varscan2
- CDK13 | c.2205del p.V736Yfs*32 | Frame Shift Del (DEL) | VAF 45/182 reads (25%) | catalogued as rs780713745; called by mutect2, pindel, varscan2
- CDK16 | c.522T>C p.G174= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV52091406; called by muse, mutect2
- CDK16 | c.1400A>T p.E467V | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as COSV52091429; called by muse, mutect2, varscan2
- CDK19 | c.1078A>G p.N360D | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV60447867; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | catalogued as rs753353408; called by mutect2, varscan2
- CDKL2 | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56732613; called by muse, mutect2, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 33/139 reads (24%) | catalogued as rs753494539; called by mutect2, varscan2
- CDS1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs771001468, COSV55687144, COSV55687463; called by muse, varscan2
- CEACAM1 | c.1069A>C p.I357L | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV50725859; called by muse, mutect2, varscan2
- CEACAM3 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1555825379, COSV55761120; called by muse, mutect2, varscan2
- CEACAM7 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV50072603, COSV50072737; called by muse, mutect2
- CEL | c.212A>G p.H71R (on ENST00000673714; = p.H68R on NM_001807.6) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV100672799; called by muse, mutect2, varscan2
- CELSR1 | c.2881G>A p.V961M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53085757; called by muse, mutect2, varscan2
- CELSR2 | c.1182T>A p.D394E | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54768585; called by muse, mutect2, varscan2
- CELSR3 | c.3500C>A p.P1167H | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50842792; called by muse, mutect2, varscan2
- CENPO | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 159/824 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV53165370; called by muse, mutect2, varscan2
- CEP120 | c.2015T>C p.L672P | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60264629; called by muse, mutect2, varscan2
- CEP120 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60264636; called by muse, mutect2, varscan2
- CEP126 | c.394+2T>A p.X132_splice | Splice Site (SNP) | VAF 18/81 reads (22%) | catalogued as COSV54823056; called by muse, mutect2, varscan2
- CEP128 | c.1387A>G p.S463G | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV55371232; called by muse, mutect2, varscan2
- CEP135 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs200040205; called by muse, mutect2, varscan2
- CEP152 | c.1320C>T p.S440= | Splice Region (SNP) | VAF 14/122 reads (11%) | catalogued as rs372008720; called by muse, mutect2, varscan2
- CEP164 | c.3705A>T p.E1235D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV54039372; called by muse, mutect2
- CEP192 | c.7432C>T p.P2478S | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58061454; called by muse, mutect2, varscan2
- CEP57 | c.1261T>A p.Y421N | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV57687634; called by muse, varscan2
- CEP72 | c.787T>C p.C263R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.143); catalogued as COSV53791099; called by muse, mutect2, varscan2
- CEP85 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247573020, COSV53327774; called by muse, varscan2
- CEP85L | c.1023T>C p.V341= | Splice Region (SNP) | VAF 25/144 reads (17%) | catalogued as COSV63821331; called by muse, mutect2, varscan2
- CETN1 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV59121063; called by muse, mutect2, varscan2
- CFAP20DC | c.655A>G p.T219A (on ENST00000482387 / NM_001351530.2; = p.T94A on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/310 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV55917626; called by muse, mutect2, varscan2
- CFAP298 | c.534+2T>C p.X178_splice | Splice Site (SNP) | VAF 30/123 reads (24%) | catalogued as COSV51591372; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 30/187 reads (16%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP43 | c.3476A>G p.K1159R | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV63852444; called by muse, mutect2
- CFAP44 | c.1641T>A p.D547E | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV55609842; called by muse, mutect2, varscan2
- CFAP46 | c.7034T>C p.V2345A | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV99585545; called by muse, mutect2, varscan2
- CFAP61 | c.1190A>G p.E397G | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55622958; called by muse, mutect2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs778664468; called by mutect2, pindel
- CFHR2 | c.708A>G p.I236M | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV66380716; called by muse, mutect2, varscan2
- CGRRF1 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV53595857; called by muse, mutect2, varscan2
- CHAF1A | c.554A>C p.E185A | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs776340717, COSV56670991; called by muse, mutect2, varscan2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2
- CHD5 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV52410325; called by muse, mutect2, varscan2
- CHD6 | c.6751G>A p.A2251T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV64689006; called by muse, mutect2, varscan2
- CHD7 | c.3627G>T p.E1209D | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71107934; called by muse, varscan2
- CHD9 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV68297462; called by muse, mutect2, varscan2
- CHDH | c.853A>G p.R285G | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.331); catalogued as COSV59456461; called by muse, mutect2, varscan2
- CHIA | c.386A>C p.Q129P (on ENST00000343320; = p.Q21P on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV58474307; called by muse, mutect2, varscan2
- CHKB | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV56415569; called by muse, mutect2, varscan2
- CHM | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63300080; called by muse, mutect2, varscan2
- CHMP7 | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV57532570; called by muse, mutect2, varscan2
- CHORDC1 | c.329+2T>C p.X110_splice | Splice Site (SNP) | VAF 55/280 reads (20%) | catalogued as COSV57705636; called by muse, mutect2, varscan2
- CHRNA9 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV59573840; called by muse, mutect2, varscan2
- CHST1 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV57322598, COSV57323456; called by muse, mutect2, varscan2
- CHST12 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1310083399, COSV51674285; called by muse, mutect2, varscan2
- CHST8 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1428120398, COSV99381642; called by muse, mutect2
- CIBAR1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63896982; called by muse, mutect2, varscan2
- CIITA | c.2158C>A p.L720M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.428); catalogued as COSV60855103; called by muse, mutect2, varscan2
- CIP2A | c.1531A>G p.T511A | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV55417735; called by muse, mutect2, varscan2
- CIZ1 | c.859A>T p.M287L | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV52970662; called by muse, mutect2, varscan2
- CKAP2 | c.725T>C p.F242S (on ENST00000378037 / NM_001098525.2; = p.F241S on NM_018204.5) | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV51621299, COSV51621928; called by muse, mutect2, varscan2
- CKAP4 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1279712510, COSV65172236; called by muse, mutect2, varscan2
- CKMT1A | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs142460452; called by muse, mutect2, varscan2
- CLCA2 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 129/499 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs781089415, COSV65286170; called by muse, mutect2, varscan2
- CLCN2 | c.2068del p.E690Rfs*6 | Frame Shift Del (DEL) | VAF 47/229 reads (21%) | catalogued as rs765672654; called by mutect2, pindel, varscan2
- CLCN3 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); catalogued as rs1034994754, COSV61626605; called by muse, mutect2, varscan2
- CLCN4 | c.1727T>A p.I576N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66465634; called by muse, mutect2, varscan2
- CLDN16 | c.556T>C p.C186R | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53227257; called by muse, mutect2, varscan2
- CLDN23 | c.395T>G p.V132G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV67731463; called by muse, mutect2, varscan2
- CLDN9 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV60910295; called by muse, mutect2, varscan2
- CLEC4M | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as rs140767813; called by muse, mutect2, varscan2
- CLGN | c.1676A>G p.K559R | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.321); catalogued as COSV57773684; called by muse, mutect2, varscan2
- CLHC1 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV68463783; called by muse, mutect2, varscan2
- CLIP3 | c.587T>C p.F196S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62111990; called by muse, mutect2
- CLK4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs765975776, COSV60318024; called by muse, mutect2, varscan2
- CLN3 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV60489352; called by muse, mutect2, varscan2
- CLPTM1L | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV57989756; called by muse, mutect2, varscan2
- CLSPN | c.3859A>G p.T1287A | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV52048142; called by muse, mutect2, varscan2
- CLTC | c.3490G>A p.A1164T | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.342); catalogued as COSV52245863; called by muse, mutect2, varscan2
- CLUH | c.590G>A p.R197Q (on ENST00000435359; = p.R235Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs770933896, COSV70928175; called by muse, mutect2
- CMIP | c.1739A>G p.N580S (on ENST00000537098 / NM_198390.2; = p.N486S on NM_030629.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV67697510; called by muse, mutect2
- CMTR2 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV100579355, COSV57602864; called by muse, mutect2, varscan2
- CMYA5 | c.9906T>A p.Y3302* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | catalogued as COSV71404607; called by muse, varscan2
- CNBD2 | c.1639A>G p.I547V (on ENST00000373973 / NM_001365709.1; = p.I543V on NM_080834.4) | Missense Mutation (SNP) | VAF 97/463 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs772455312, COSV100839172; called by muse, mutect2, varscan2
- CNGA3 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs201713771, COSV55623063; called by muse, mutect2, varscan2
- CNGA4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs763651032, COSV66005402; called by muse, mutect2, varscan2
- CNIH3 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 79/499 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV55273707; called by muse, mutect2, varscan2
- CNIH3 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55273715; called by muse, mutect2, varscan2
- CNKSR2 | c.1544T>C p.L515S | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.428); catalogued as COSV54251880; called by muse, mutect2, varscan2
- CNNM4 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65660425, COSV65661550; called by muse, mutect2, varscan2
- CNOT1 | c.6770A>G p.D2257G | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV55314449, COSV99800976; called by muse, mutect2, varscan2
- CNOT1 | c.1234T>C p.S412P | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as COSV57766935; called by muse, mutect2, varscan2
- CNOT6 | c.973A>G p.N325D | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56159775; called by muse, mutect2, varscan2
- CNR1 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs764560714, COSV62986478; called by muse, mutect2, varscan2
- CNTN5 | c.3198A>G p.S1066= | Splice Region (SNP) | VAF 19/114 reads (17%) | catalogued as COSV54291990; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 32/159 reads (20%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP1 | c.2530+2T>C p.X844_splice | Splice Site (SNP) | VAF 40/209 reads (19%) | catalogued as COSV52848660; called by muse, mutect2, varscan2
- CNTNAP5 | c.2097G>T p.W699C | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV70478227; called by muse, mutect2
- COA7 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV65299243; called by muse, mutect2, varscan2
- COBL | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs376448766; called by muse, mutect2, varscan2
- COL12A1 | c.4963G>A p.V1655M | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as rs749368197, COSV59389327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.4605+2T>C p.X1535_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV52849796; called by muse, mutect2, varscan2
- COL15A1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs199564502, COSV100897694; called by muse, mutect2, varscan2
- COL19A1 | c.1336A>G p.N446D | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.137); catalogued as COSV59568349; called by muse, mutect2, varscan2
- COL19A1 | c.3196G>A p.G1066R | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156867234, COSV100507139, COSV59564466; called by muse, mutect2, varscan2
- COL22A1 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs776540980, COSV57327118; called by mutect2, varscan2
- COL24A1 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65303715; called by muse, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 20/76 reads (26%) | catalogued as rs760493024; called by mutect2, varscan2
- COL28A1 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV68081149; called by muse, mutect2, varscan2
- COL3A1 | c.3688A>G p.N1230D | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as COSV58584274; called by muse, mutect2, varscan2
- COL4A2 | c.4275del p.G1426Efs*33 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | catalogued as COSV100847412, COSV64631360; called by mutect2, pindel, varscan2
- COL4A3 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV67414012; called by muse, mutect2, varscan2
- COL4A6 | c.3826G>A p.A1276T | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs113329155, COSV57858534, COSV57861537, COSV99058972; called by muse, mutect2, varscan2
- COL6A2 | c.2405A>G p.E802G | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs1018641177, COSV100154226; called by muse, mutect2, varscan2
- COL6A3 | c.2270A>T p.D757V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769363327, COSV55083478; called by muse, mutect2, varscan2
- COL6A6 | c.6773C>A p.A2258D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV62020443; called by muse, mutect2, varscan2
- COL7A1 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); catalogued as COSV60392905; called by muse, mutect2, varscan2
- COLGALT1 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53107975; called by muse, mutect2, varscan2
- COMMD1 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV61274685; called by muse, mutect2, varscan2
- COMT | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52889407; called by muse, mutect2, varscan2
- COP1 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58164611; called by muse, mutect2, varscan2
- COPA | c.2057A>G p.N686S | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV54099686; called by muse, mutect2, varscan2
- COPA | c.1910T>C p.V637A | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54099704; called by muse, mutect2, varscan2
- COPA | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as rs199634303, COSV54099727; called by muse, mutect2, varscan2
- COPB1 | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | catalogued as COSV51447327; called by muse, mutect2, varscan2
- COPB2 | c.2414T>C p.F805S | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV60349410; called by muse, mutect2, varscan2
- COPS5 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63474235; called by muse, mutect2, varscan2
- COQ3 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54639318; called by muse, mutect2, varscan2
- COQ7 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs201474239, COSV58981417; called by muse, mutect2, varscan2
- CORO1A | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1327483966, COSV54630725; called by muse, mutect2, varscan2
- COX11 | c.786dup p.E263* | Frame Shift Ins (INS) | VAF 43/155 reads (28%) | catalogued as rs778099821; called by mutect2, varscan2
- COX7A2L | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as rs61754513, COSV52242878; called by muse, mutect2, varscan2
- CPAMD8 | c.3055C>T p.R1019C (on ENST00000651564; = p.R972C on NM_015692.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs201681851; called by muse, mutect2, varscan2
- CPAMD8 | c.2216C>T p.T739M (on ENST00000651564; = p.T692M on NM_015692.5) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs753298491, COSV52232485; called by muse, mutect2, varscan2
- CPEB3 | c.1183T>C p.F395L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV56454587; called by muse, mutect2, varscan2
- CPNE6 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV53743073; called by muse, mutect2, varscan2
- CPNE9 | c.1394T>C p.M465T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56067977; called by muse, mutect2
- CPPED1 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55496400; called by muse, mutect2, varscan2
- CPQ | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs753340797, COSV55140372; called by muse, mutect2, varscan2
- CPS1 | c.2734T>A p.F912I | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51805029; called by muse, mutect2, varscan2
- CPSF1 | c.3821G>A p.R1274H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as rs781806525, COSV58232740; called by muse, mutect2, varscan2
- CPT2 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53758874; called by muse, mutect2, varscan2
- CPTP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375729538, COSV59562612; called by muse, mutect2, varscan2
- CPXM2 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53858511; called by muse, mutect2
- CR1 | c.217T>C p.C73R | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65456815; called by muse, mutect2, varscan2
- CR1L | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54323683; called by muse, varscan2
- CR2 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV65506473; called by muse, mutect2, varscan2
- CRAT | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs747989201, COSV58876436; called by muse, mutect2, varscan2
- CRB2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs571013901, COSV63502278; called by muse, mutect2, varscan2
- CRELD1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs759093681, COSV55976663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRLF2 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV67493531; called by muse, mutect2, varscan2
- CRMP1 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV61478356, COSV61478849; called by muse, mutect2, varscan2
- CRNKL1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757086001, COSV66105596; called by muse, varscan2
- CRYBA4 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs776063006, COSV61321391; called by muse, mutect2, varscan2
- CRYBG2 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.031); catalogued as rs748616711; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 42/203 reads (21%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CRYGC | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs372921291; called by mutect2, varscan2
- CRYM | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as COSV54830259, COSV54830875; called by muse, mutect2, varscan2
- CSMD1 | c.2200T>C p.S734P (on ENST00000520002; = p.S733P on NM_033225.6) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59297223; called by muse, mutect2
- CSMD2 | c.4039del p.L1347Cfs*80 | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | catalogued as COSV53938772; called by mutect2, pindel, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSMD3 | c.10307A>G p.Y3436C (on ENST00000297405 / NM_001363185.1; = p.Y3267C on NM_052900.3) | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754532783, COSV52130858; called by muse, mutect2, varscan2
- CSMD3 | c.2114A>G p.Q705R (on ENST00000297405 / NM_001363185.1; = p.Q601R on NM_052900.3) | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs759587996, COSV52130890; called by muse, mutect2, varscan2
- CSNK1E | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV63290524; called by muse, varscan2
- CSNK1E | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as COSV63290529; called by muse, varscan2
- CSNK1G3 | c.563T>C p.L188S | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62053813; called by muse, mutect2, varscan2
- CSNK2A1 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53934110; called by muse, varscan2
- CSRNP2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV50396925; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | catalogued as rs756924682; called by mutect2, varscan2
- CTAGE1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs780250842, COSV66943089; called by muse, mutect2, varscan2
- CTC1 | c.1931A>G p.D644G | Missense Mutation (SNP) | VAF 81/367 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59852567; called by muse, mutect2, varscan2
- CTCF | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV50463289; called by muse, mutect2
- CTDP1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143464787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57071132; called by muse, mutect2, varscan2
- CTNNA2 | c.2093A>C p.D698A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58141492; called by muse, mutect2, varscan2
- CTNNA3 | c.2160-2A>G p.X720_splice | Splice Site (SNP) | VAF 40/178 reads (22%) | catalogued as COSV65522536; called by muse, mutect2, varscan2
- CTNND1 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.369); catalogued as COSV62382594; called by muse, mutect2, varscan2
- CTNND2 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58873392; called by muse, mutect2, varscan2
- CTSF | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.819); catalogued as COSV59747892; called by muse, mutect2, varscan2
- CTSW | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV57171938; called by muse, mutect2
- CUBN | c.4921T>C p.Y1641H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV64710572; called by muse, mutect2, varscan2
- CUL5 | c.1577T>C p.V526A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV67608368, COSV67608416; called by muse, mutect2, varscan2
- CUL7 | c.3167C>T p.S1056F | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV54822001; called by muse, mutect2, varscan2
- CWF19L2 | c.1306T>C p.S436P | Missense Mutation (SNP) | VAF 90/523 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56510253; called by muse, mutect2, varscan2
- CWH43 | c.234T>C p.I78= | Splice Region (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56937145; called by muse, mutect2
- CWH43 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750492411, COSV56937160; called by muse, mutect2, varscan2
- CXXC1 | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV53273636; called by muse, mutect2, varscan2
- CYLD | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.143); catalogued as COSV61093504; called by muse, mutect2, varscan2
- CYP11B2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as rs202173105, COSV59995171; called by muse, mutect2, varscan2
- CYP19A1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV53057973; called by muse, mutect2, varscan2
- CYP2A6 | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV56534306; called by muse, mutect2, varscan2
- CYP2A7 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV52499232; called by muse, mutect2, varscan2
- CYP2C18 | c.1181T>C p.V394A | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV53670634; called by muse, mutect2, varscan2
- CYP2E1 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV53312757; called by muse, mutect2
- CYP3A43 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55935451; called by muse, mutect2, varscan2
- CYP51A1 | c.1094A>T p.D365V | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs1426032093, COSV50151086; called by muse, mutect2, varscan2
- CYTIP | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV51632815; called by muse, mutect2, varscan2
- CYYR1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54829176; called by muse, mutect2, varscan2
- DAB2 | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57913076; called by muse, mutect2, varscan2
- DACH1 | c.1927G>A p.V643I (on ENST00000619232 / NM_001366712.1; = p.V389I on NM_004392.6) | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.109); catalogued as COSV57493274; called by muse, mutect2, varscan2
- DACH2 | c.77A>G p.E26G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV64164212; called by muse, varscan2
- DAGLA | c.2173A>G p.S725G | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57194843; called by muse, mutect2, varscan2
- DAND5 | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV57683977; called by muse, mutect2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCAF11 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs776938647, COSV58108562; called by muse, mutect2, varscan2
- DCAF17 | c.1231del p.S411Vfs*23 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs755674655; called by mutect2, varscan2
- DCHS1 | c.623T>C p.V208A | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55032449; called by muse, mutect2, varscan2
- DCLRE1B | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs756071075, COSV56723872; called by muse, mutect2, varscan2
- DCLRE1B | c.805C>A p.H269N | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV65812352; called by muse, mutect2, varscan2
- DCT | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs535988751, COSV65468037; called by muse, mutect2, varscan2
- DCTN1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs765995146, COSV62619884; called by muse, mutect2, varscan2
- DDHD2 | c.411+2T>C p.X137_splice | Splice Site (SNP) | VAF 38/209 reads (18%) | catalogued as COSV68157426; called by muse, mutect2, varscan2
- DDIT3 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV56253208; called by muse, mutect2, varscan2
- DDIT4L | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV56767079; called by muse, mutect2
- DDR1 | c.2630C>T p.P877L (on ENST00000324771; = p.P840L on NM_001954.4) | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776556090, COSV61320137; called by muse, mutect2, varscan2
- DDX18 | c.1804A>G p.N602D | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV54305773; called by muse, mutect2, varscan2
- DDX46 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV62798757; called by muse, mutect2, varscan2
- DDX50 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV65291886; called by muse, mutect2, varscan2
- DDX54 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1210402204, COSV58372447; called by muse, mutect2, varscan2
- DDX55 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761069639, COSV53015619; called by muse, mutect2, varscan2
- DDX56 | c.1403C>A p.P468H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51835721; called by muse, mutect2, varscan2
- DDX58 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65882620; called by muse, mutect2, varscan2
- DDX60 | c.4557G>T p.E1519D | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV67095666; called by muse, mutect2, varscan2
- DDX60L | c.3251T>C p.L1084S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52710525; called by muse, mutect2
- DENND1A | c.1334T>G p.V445G | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV65323708; called by muse, mutect2, varscan2
- DENND4A | c.3641A>G p.N1214S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); catalogued as COSV71265430; called by muse, mutect2, varscan2
- DENND4B | c.2465T>C p.L822P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV63407847; called by muse, mutect2, varscan2
- DENND5B | c.3401T>C p.V1134A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV60900840; called by muse, mutect2, varscan2
- DEPDC5 | c.1910A>G p.D637G (on ENST00000400246; = p.D715G on NM_014662.5) | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV56693291; called by muse, varscan2
- DEPTOR | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV53813842; called by muse, mutect2, varscan2
- DEPTOR | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53813849; called by muse, mutect2, varscan2
4,115 further variants in this file (2,901 protein-altering or splice-affecting, 1,117 silent, 97 other) are not listed here.
